Somatic mutation profile of tumor specimen TCGA-BL-A0C8-01B (aliquot TCGA-BL-A0C8-01B-04D-A271-08) from TCGA case TCGA-BL-A0C8, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Dome of bladder; AJCC pathologic stage: Stage I; Age at diagnosis: 73.4 years (26,819 days).
Specimen TCGA-BL-A0C8-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 06fe60be-3ead-45c3-be29-3f4a243ddc8a.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-BL-A0C8-10A (Blood Derived Normal), aliquot TCGA-BL-A0C8-10A-01D-A10S-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/08fa9483-7112-405f-8675-37fd896af800

The open-access MAF lists 126 somatic variants for this specimen: 89 protein-altering or splice-affecting, 36 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 73, Silent 36, Nonsense Mutation 6, Frame Shift Ins 5, Frame Shift Del 2, Splice Site 2, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- LDLR | c.1576C>T p.P526S | Missense Mutation (SNP) | VAF 18/32 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs730882106, CM100938, CM920460, COSV52942440; ClinVar: uncertain significance / pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- SF3B1 | c.2704G>A p.E902K | Missense Mutation (SNP) | VAF 81/108 reads (75%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV59206538, COSV59210925; called by muse, mutect2, varscan2
- ADAMTS14 | c.3622G>C p.D1208H | Missense Mutation (SNP) | VAF 10/39 reads (26%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.443); catalogued as COSV64607212; called by muse, mutect2, varscan2
- ADK | c.613G>A p.E205K (on ENST00000286621; = p.E188K on NM_001123.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 81/198 reads (41%) | SIFT tolerated (0.22); PolyPhen benign (0.005); catalogued as COSV54221236; called by muse, mutect2, varscan2
- AMIGO3 | c.835C>G p.L279V | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT tolerated (0.53); PolyPhen benign (0.011); catalogued as COSV57540464; called by muse, mutect2, varscan2
- ARID1A | c.3546del p.S1182Rfs*24 | Frame Shift Del (DEL) | VAF 9/24 reads (38%) | catalogued as COSV61390590; called by mutect2, pindel, varscan2
- BRAT1 | c.280C>T p.Q94* | Nonsense Mutation (SNP) | VAF 20/38 reads (53%) | catalogued as COSV100500741; called by muse, mutect2, varscan2
- BRCA2 | c.6290C>T p.T2097M | Missense Mutation (SNP) | VAF 12/62 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.406); catalogued as rs80358866; ClinVar: benign / conflicting interpretations of pathogenicity / likely benign; called by muse, mutect2, varscan2
- CACNA2D2 | c.3306C>A p.N1102K (on ENST00000479441 / NM_001174051.3; = p.N1095K on NM_006030.4) | Missense Mutation (SNP) | VAF 27/55 reads (49%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV56570044; called by muse, mutect2, varscan2
- CAPN10 | c.1696C>T p.R566W | Missense Mutation (SNP) | VAF 10/27 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.521); catalogued as rs757430028, COSV54380325; called by muse, mutect2, varscan2
- CDR2 | c.22G>C p.E8Q | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.085); catalogued as COSV51676766; called by muse, mutect2, varscan2
- CNGA1 | c.824C>T p.S275F | Missense Mutation (SNP) | VAF 17/42 reads (40%) | SIFT deleterious (0.03); PolyPhen benign (0.102); catalogued as COSV62057330; called by muse, mutect2, varscan2
- COL1A2 | c.2025+1G>A p.X675_splice | Splice Site (SNP) | VAF 42/88 reads (48%) | catalogued as COSV51967658; called by muse, mutect2, varscan2
- COL27A1 | c.1726A>G p.S576G | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT tolerated (0.24); PolyPhen benign (0); catalogued as COSV61931409; called by muse, mutect2
- COL9A2 | c.2012G>C p.G671A | Missense Mutation (SNP) | VAF 23/42 reads (55%) | SIFT tolerated (0.48); PolyPhen benign (0.1); catalogued as COSV65624310; called by muse, mutect2, varscan2
- CRAT | c.1214A>G p.Q405R | Missense Mutation (SNP) | VAF 15/91 reads (16%) | SIFT tolerated (0.16); PolyPhen benign (0.017); catalogued as COSV58879425; called by muse, mutect2, varscan2
- DCHS2 | n.6126G>A | Splice Region (SNP) | VAF 5/36 reads (14%) | catalogued as rs899182469, COSV100601859, COSV61781259; called by muse, mutect2, varscan2
- EEF1AKMT4-ECE2 | c.2461G>A p.V821M | Missense Mutation (SNP) | VAF 18/90 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as rs541647645, COSV62570217; called by muse, mutect2, varscan2
- EFHB | c.1660C>T p.H554Y | Missense Mutation (SNP) | VAF 10/49 reads (20%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.837); catalogued as COSV55554633; called by muse, mutect2, varscan2
- EHMT1 | c.3161G>A p.R1054K | Missense Mutation (SNP) | VAF 12/29 reads (41%) | SIFT tolerated (0.15); PolyPhen benign (0.405); catalogued as COSV71778842; called by muse, mutect2, varscan2
- ELP1 | c.824A>G p.H275R | Missense Mutation (SNP) | VAF 17/94 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1564100993, COSV65900330; called by muse, mutect2, varscan2
- FAM50B | c.865G>A p.A289T | Missense Mutation (SNP) | VAF 7/30 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV66655351; called by muse, mutect2
- FBXO8 | c.880C>T p.R294C | Missense Mutation (SNP) | VAF 23/82 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.971); catalogued as COSV67032468; called by muse, mutect2, varscan2
- FGD1 | c.1096G>T p.V366L | Missense Mutation (SNP) | VAF 11/15 reads (73%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV64309100, COSV64309824; called by muse, mutect2, varscan2
- FIGN | c.981_982insT p.D328* | Frame Shift Ins (INS) | VAF 53/103 reads (51%) | catalogued as COSV60772407; called by mutect2, pindel, varscan2
- FMO2 | c.94G>C p.E32Q | Missense Mutation (SNP) | VAF 52/194 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV52950726, COSV99268965; called by muse, mutect2, varscan2
- GABBR2 | c.688G>A p.E230K | Missense Mutation (SNP) | VAF 8/61 reads (13%) | SIFT tolerated (0.12); PolyPhen benign (0.06); catalogued as COSV52321929; called by muse, mutect2, varscan2
- GOLGB1 | c.8344_8345dup p.D2782Efs*12 | Frame Shift Ins (INS) | VAF 13/49 reads (27%) | catalogued as rs747719358; called by mutect2, varscan2
- GPN3 | c.7C>T p.R3W | Missense Mutation (SNP) | VAF 19/81 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV57402880; called by muse, mutect2, varscan2
- GRIA4 | c.977G>C p.G326A | Missense Mutation (SNP) | VAF 30/69 reads (43%) | SIFT deleterious (0.05); PolyPhen benign (0.399); catalogued as COSV56923168; called by muse, mutect2, varscan2
- GUCY1A1 | c.1113C>G p.I371M | Missense Mutation (SNP) | VAF 17/52 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56651320; called by muse, mutect2, varscan2
- H3C7 | c.142G>A p.A48T | Missense Mutation (SNP) | VAF 13/103 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.117); catalogued as COSV55101176; called by muse, mutect2, varscan2
- HIP1R | c.1895C>T p.A632V | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0); PolyPhen benign (0.034); catalogued as rs376717149; called by muse, mutect2, varscan2
- HOXA11 | c.449C>T p.T150I | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT tolerated (0.19); PolyPhen benign (0.264); catalogued as rs1329201248; called by muse, mutect2
- HSPB11 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 40/86 reads (47%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs769134105, COSV52042183; called by muse, mutect2, varscan2
- LRFN3 | c.1184_1190del p.T395Mfs*37 | Frame Shift Del (DEL) | VAF 21/41 reads (51%) | catalogued as COSV55819301; called by mutect2, pindel, varscan2
- MAN2A2 | c.198G>C p.E66D | Missense Mutation (SNP) | VAF 53/90 reads (59%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as rs1374889309, COSV64640189; called by muse, mutect2, varscan2
- MEGF8 | c.8048G>A p.R2683H (on ENST00000251268 / NM_001271938.2; = p.R2616H on NM_001410.3) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.965); catalogued as rs950869878, COSV99239567; called by muse, mutect2
- NBR1 | c.814C>G p.H272D | Missense Mutation (SNP) | VAF 29/41 reads (71%) | SIFT tolerated (0.21); PolyPhen benign (0.048); catalogued as COSV57836189; called by muse, mutect2, varscan2
- NECTIN4 | c.617C>T p.S206L | Missense Mutation (SNP) | VAF 27/187 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.858); catalogued as rs773290658, COSV63514198; called by muse, mutect2, varscan2
- NES | c.4G>C p.E2Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); catalogued as COSV63963307; called by muse, mutect2, varscan2
- NUP153 | c.586A>G p.I196V | Missense Mutation (SNP) | VAF 5/36 reads (14%) | SIFT tolerated (0.54); PolyPhen benign (0.168); catalogued as rs766711664, COSV50469770; called by mutect2, varscan2
- NVL | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 15/44 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as rs1471505454, COSV55876864; called by muse, mutect2, varscan2
- OLFM4 | c.1244T>G p.L415R | Missense Mutation (SNP) | VAF 14/58 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54580976; called by muse, mutect2, varscan2
- OR2T6 | c.130G>A p.V44I | Missense Mutation (SNP) | VAF 11/58 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0.003); catalogued as COSV63217180; called by muse, mutect2, varscan2
- OR6C70 | c.316G>A p.G106R | Missense Mutation (SNP) | VAF 12/66 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.916); catalogued as rs766194991, COSV59245537; called by muse, mutect2, varscan2
- OR8H1 | c.18C>A p.N6K | Missense Mutation (SNP) | VAF 12/67 reads (18%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as COSV57294916; called by muse, mutect2, varscan2
- OTUD7A | c.922G>A p.E308K (on ENST00000307050 / NM_001382637.1; = p.E301K on NM_130901.3) | Missense Mutation (SNP) | VAF 31/62 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs754202329, COSV61044183; called by muse, mutect2, varscan2
- PLXNA4 | c.1927G>A p.G643S | Missense Mutation (SNP) | VAF 77/157 reads (49%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.999); catalogued as rs1460318926, COSV58116136; called by muse, mutect2, varscan2
- PMS1 | c.1592A>G p.N531S | Missense Mutation (SNP) | VAF 27/43 reads (63%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as COSV59720818; called by muse, mutect2, varscan2
- POLN | c.1825G>T p.A609S | Missense Mutation (SNP) | VAF 58/114 reads (51%) | SIFT tolerated (0.27); PolyPhen benign (0.014); catalogued as COSV67027996; called by muse, mutect2, varscan2
- PTPRK | c.1220C>T p.A407V | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.935); catalogued as COSV63908907; called by muse, mutect2, varscan2
- RAB5A | c.452A>C p.Y151S | Missense Mutation (SNP) | VAF 37/98 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.962); catalogued as COSV56086342; called by muse, mutect2, varscan2
- RADIL | c.2144G>C p.S715T | Missense Mutation (SNP) | VAF 17/49 reads (35%) | SIFT tolerated (0.44); PolyPhen benign (0.095); catalogued as COSV68204092; called by muse, mutect2
- RELCH | c.3182C>G p.S1061C | Missense Mutation (SNP) | VAF 49/99 reads (49%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.965); catalogued as COSV56893697; called by muse, mutect2, varscan2
- RIPK1 | c.950G>C p.R317T | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV52532345, COSV99454903; called by muse, mutect2, varscan2
- RNF123 | c.625C>G p.L209V | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0.094); catalogued as COSV59690989; called by muse, mutect2, varscan2
- SATB2 | c.1951C>T p.Q651* | Nonsense Mutation (SNP) | VAF 10/50 reads (20%) | catalogued as COSV53483325, COSV99612930; called by muse, mutect2, varscan2
- SDCCAG8 | c.811C>G p.L271V | Missense Mutation (SNP) | VAF 51/90 reads (57%) | SIFT tolerated (0.42); PolyPhen benign (0.01); catalogued as COSV59419113; called by muse, mutect2, varscan2
- SLC23A3 | c.340C>G p.P114A | Missense Mutation (SNP) | VAF 43/67 reads (64%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV55409907; called by muse, mutect2, varscan2
- SLC6A9 | c.727C>T p.R243W (on ENST00000360584 / NM_201649.4; = p.R189W on NM_006934.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/91 reads (14%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.663); catalogued as rs774340135, COSV62211007; called by muse, mutect2, varscan2
- SNX22 | c.545C>G p.A182G | Missense Mutation (SNP) | VAF 16/122 reads (13%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.091); catalogued as COSV55521575; called by muse, mutect2, varscan2
- SPATS2 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 12/42 reads (29%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV58924432; called by muse, varscan2
- SPATS2 | c.454G>A p.E152K | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.881); catalogued as COSV58924441; called by muse, varscan2
- SRC | c.17G>A p.S6N | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.914); catalogued as COSV62441509; called by muse, mutect2, varscan2
- SYNE2 | c.7300C>T p.R2434W | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.328); catalogued as rs570233690, COSV59973219; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SYNE2 | c.8815G>C p.E2939Q | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.31); PolyPhen benign (0.015); catalogued as COSV59973231; called by muse, mutect2, varscan2
- TARS3 | c.1819G>A p.E607K | Missense Mutation (SNP) | VAF 5/35 reads (14%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as COSV60107342; called by muse, mutect2, varscan2
- TCFL5 | c.844T>G p.S282A | Missense Mutation (SNP) | VAF 12/58 reads (21%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as COSV53899510; called by muse, mutect2
- TNC | c.991T>G p.Y331D | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.13); catalogued as COSV60791527; called by muse, mutect2, varscan2
- TRERF1 | c.1192C>T p.Q398* | Nonsense Mutation (SNP) | VAF 49/83 reads (59%) | catalogued as COSV100551895; called by muse, mutect2, varscan2
- UNC13C | c.1123C>T p.R375* | Nonsense Mutation (SNP) | VAF 18/31 reads (58%) | catalogued as rs1337986902, COSV52882831; called by muse, mutect2, varscan2
- UNC13C | c.1831C>T p.Q611* | Nonsense Mutation (SNP) | VAF 38/77 reads (49%) | catalogued as COSV99523876; called by muse, mutect2, varscan2
- USO1 | c.513G>C p.L171F | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); catalogued as COSV53711429; called by muse, mutect2, varscan2
- USP34 | c.10345G>C p.E3449Q | Missense Mutation (SNP) | VAF 14/61 reads (23%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.023); catalogued as COSV63725966; called by mutect2, varscan2
- USP34 | c.853C>T p.R285* | Nonsense Mutation (SNP) | VAF 5/28 reads (18%) | catalogued as COSV68401388; called by muse, mutect2, varscan2
- WDCP | c.2057C>G p.S686C | Missense Mutation (SNP) | VAF 12/59 reads (20%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.785); catalogued as rs1214817668, COSV54594135; called by muse, mutect2, varscan2
- XPO5 | c.524G>T p.R175I | Missense Mutation (SNP) | VAF 37/196 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV54835928; called by muse, mutect2, varscan2
- ZNF221 | c.1349A>G p.Y450C | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.937); catalogued as rs1443884122, COSV52111540; called by muse, mutect2, varscan2
- ZNF335 | c.3205C>G p.H1069D | Missense Mutation (SNP) | VAF 14/140 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100533482; called by muse, mutect2, varscan2
- ZNF883 | c.936G>C p.Q312H | Missense Mutation (SNP) | VAF 53/114 reads (46%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.723); catalogued as COSV71309291; called by muse, mutect2, varscan2
- ZSWIM4 | c.302C>T p.T101I | Missense Mutation (SNP) | VAF 3/29 reads (10%) | SIFT tolerated (0.4); PolyPhen benign (0.037); catalogued as rs1268488151; called by muse, mutect2
- C9orf78 | c.164G>A p.G55E | Missense Mutation (SNP) | VAF 3/16 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, varscan2
- FCGBP | c.8036T>C p.V2679A | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.823); called by mutect2, varscan2
- PDZRN3 | c.2303dup p.L769Afs*55 | Frame Shift Ins (INS) | VAF 4/26 reads (15%) | called by pindel, varscan2
- PEAR1 | c.3012dup p.G1005Rfs*4 | Frame Shift Ins (INS) | VAF 12/108 reads (11%) | called by mutect2, pindel, varscan2
- RCN3 | c.118dup p.L40Pfs*7 | Frame Shift Ins (INS) | VAF 14/66 reads (21%) | called by mutect2, pindel, varscan2
- VPS13B | c.10017+1_10017+9del p.X3339_splice | Splice Site (DEL) | VAF 8/39 reads (21%) | called by mutect2, pindel
- WASHC2A | c.3484C>A p.P1162T | Missense Mutation (SNP) | VAF 6/103 reads (6%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.53); called by muse, mutect2
- CCDC183 | c.1500C>T p.F500= | Silent (SNP) | VAF 8/16 reads (50%) | catalogued as COSV61041977; called by muse, mutect2, varscan2
- CCT3 | c.1014G>C p.L338= | Silent (SNP) | VAF 13/88 reads (15%) | catalogued as COSV55291958; called by muse, mutect2, varscan2
- CNTNAP1 | c.660C>T p.G220= | Silent (SNP) | VAF 14/30 reads (47%) | catalogued as COSV52855008; called by muse, mutect2, varscan2
- CPED1 | c.870G>T p.S290= | Silent (SNP) | VAF 15/54 reads (28%) | catalogued as rs774206526, COSV60014767; called by muse, mutect2, varscan2
- GPR151 | c.294G>A p.A98= | Silent (SNP) | VAF 13/59 reads (22%) | catalogued as rs774100549, COSV57038728; called by muse, mutect2, varscan2
- GZF1 | c.2079G>C p.L693= | Silent (SNP) | VAF 23/68 reads (34%) | catalogued as COSV57639064; called by muse, mutect2, varscan2
- HGFAC | c.1824C>T p.G608= | Silent (SNP) | VAF 18/80 reads (23%) | catalogued as rs747553396, COSV66976693; called by muse, mutect2, varscan2
- ITGA10 | c.1605C>G p.L535= | Silent (SNP) | VAF 23/109 reads (21%) | catalogued as COSV65199579; called by muse, mutect2, varscan2
- KRTAP12-3 | c.111C>T p.P37= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as rs1387918181, COSV59978977; called by muse, mutect2
- LAMC2 | c.3297C>T p.L1099= | Silent (SNP) | VAF 15/43 reads (35%) | catalogued as COSV99917334, COSV99918087; called by muse, mutect2, varscan2
- LPIN3 | c.2260C>T p.L754= | Silent (SNP) | VAF 19/39 reads (49%) | catalogued as COSV60039127; called by muse, mutect2, varscan2
- LRRC4B | c.768C>A p.R256= | Silent (SNP) | VAF 3/10 reads (30%) | called by muse, mutect2
- MARCHF1 | c.225C>A p.S75= (on ENST00000274056; = p.S58= on NM_017923.4) | Silent (SNP) | VAF 11/68 reads (16%) | catalogued as COSV56834279; called by muse, mutect2, varscan2
- MAST4 | c.7284G>A p.P2428= (on ENST00000403625 / NM_001164664.2; = p.P2239= on NM_015183.3) | Silent (SNP) | VAF 11/14 reads (79%) | catalogued as rs1303155307, COSV55115274; called by muse, mutect2, varscan2
- MCM9 | c.1045T>C p.L349= | Silent (SNP) | VAF 9/22 reads (41%) | catalogued as COSV57648987; called by muse, mutect2, varscan2
- MED22 | c.348C>G p.L116= | Silent (SNP) | VAF 26/63 reads (41%) | catalogued as COSV59300420; called by muse, mutect2, varscan2
- MIDEAS | c.2130G>A p.V710= | Silent (SNP) | VAF 8/35 reads (23%) | catalogued as COSV54099796; called by muse, mutect2, varscan2
- MST1 | c.2007G>A p.G669= | Silent (SNP) | VAF 14/71 reads (20%) | catalogued as COSV56537269; called by muse, mutect2, varscan2
- MYH1 | c.1890G>A p.A630= | Silent (SNP) | VAF 63/136 reads (46%) | catalogued as rs377184878; called by muse, mutect2, varscan2
- MYO9A | c.834A>G p.V278= | Silent (SNP) | VAF 32/70 reads (46%) | catalogued as COSV61859449; called by muse, mutect2, varscan2
- NDOR1 | c.1143G>A p.P381= | Silent (SNP) | VAF 8/21 reads (38%) | catalogued as rs749494097, COSV61289717; called by muse, mutect2, varscan2
- OPRL1 | c.144C>T p.L48= | Silent (SNP) | VAF 17/45 reads (38%) | catalogued as rs755034870, COSV61091530; called by muse, mutect2, varscan2
- PDLIM4 | c.735G>A p.P245= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as rs750840954, COSV53803934; called by muse, mutect2, varscan2
- PIGW | c.483C>G p.L161= | Silent (SNP) | VAF 40/195 reads (21%) | called by muse, mutect2, varscan2
- PRMT5 | c.366C>T p.F122= | Silent (SNP) | VAF 4/41 reads (10%) | catalogued as rs1359430442; called by muse, mutect2, varscan2
- RYR3 | c.10401G>A p.L3467= (on ENST00000389232; = p.L3468= on NM_001036.6) | Silent (SNP) | VAF 25/63 reads (40%) | catalogued as rs1451581805, COSV66810723; called by muse, mutect2, varscan2
- S100A8 | c.36C>T p.I12= | Silent (SNP) | VAF 33/145 reads (23%) | catalogued as COSV64198301; called by muse, varscan2
- SACS | c.960C>T p.V320= | Silent (SNP) | VAF 12/59 reads (20%) | catalogued as COSV66547770; called by muse, mutect2, varscan2
- SEC24A | c.2491C>T p.L831= | Silent (SNP) | VAF 47/133 reads (35%) | catalogued as COSV63275060; called by muse, varscan2
- SMOC1 | c.1230G>T p.L410= | Silent (SNP) | VAF 79/151 reads (52%) | catalogued as COSV62762366; called by muse, mutect2, varscan2
- SPTB | c.2985G>A p.R995= | Silent (SNP) | VAF 12/35 reads (34%) | catalogued as rs1471882903, COSV67631976; called by muse, mutect2, varscan2
- TMEM236 | c.294A>G p.T98= | Silent (SNP) | VAF 39/149 reads (26%) | catalogued as rs1333499066, COSV57738822; called by muse, mutect2, varscan2
- TMEM8B | c.444G>A p.P148= | Silent (SNP) | VAF 4/30 reads (13%) | catalogued as rs557315408; called by mutect2, varscan2
- TPTE2 | c.438C>A p.A146= | Silent (SNP) | VAF 5/29 reads (17%) | catalogued as COSV55029685; called by muse, mutect2
- VIL1 | c.333C>T p.F111= | Silent (SNP) | VAF 28/43 reads (65%) | catalogued as COSV50300274; called by muse, mutect2, varscan2
- ZFHX3 | c.2979C>T p.T993= | Silent (SNP) | VAF 8/15 reads (53%) | catalogued as COSV51707874, COSV51739276; called by muse, mutect2, varscan2
- PTGR1 | c.652-1573C>G | Intron (SNP) | VAF 11/43 reads (26%) | catalogued as COSV99437713; called by muse, mutect2, varscan2
